Somatic mutation profile of tumor specimen TCGA-BG-A0MI-01A (aliquot TCGA-BG-A0MI-01A-11W-A062-09) from TCGA case TCGA-BG-A0MI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 83.0 years (30,334 days).
Specimen TCGA-BG-A0MI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4060719-f691-4c1c-989e-ec32314618a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0MI-10A (Blood Derived Normal), aliquot TCGA-BG-A0MI-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c39da781-2d30-411c-ba88-029b2b112808

The open-access MAF lists 68 somatic variants for this specimen: 49 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 16, Frame Shift Ins 2, Frame Shift Del 1, In Frame Del 1, Splice Region 1, Nonsense Mutation 1, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 59/164 reads (36%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 36/88 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1724_1729del p.K575_T576del (on ENST00000521381 / NM_181523.3; = p.K305_T306del on NM_181504.4) | In Frame Del (DEL) | VAF 47/128 reads (37%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 29/75 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64295132, COSV64296674, COSV64298389; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 113/285 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs756321624, COSV53051870; called by muse, mutect2, varscan2
- ADGRF5 | c.2855C>T p.T952M | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs749091129, COSV51935488; called by muse, mutect2, varscan2
- AGGF1 | c.1470G>A p.P490= | Splice Region (SNP) | VAF 26/101 reads (26%) | catalogued as rs761261870, COSV57229565; called by muse, mutect2, varscan2
- AMPD3 | c.1330G>T p.G444C (on ENST00000396553 / NM_001025389.2; = p.G453C on NM_000480.3) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67331333; called by muse, mutect2, varscan2
- CADPS | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs752666502, COSV51885333; called by muse, mutect2, varscan2
- CCN2 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV63466782; called by muse, mutect2, varscan2
- CD209 | c.463G>C p.A155P | Missense Mutation (SNP) | VAF 264/679 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV52654868; called by muse, mutect2, varscan2
- CDH19 | c.1940G>T p.G647V | Missense Mutation (SNP) | VAF 110/312 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1490297248, COSV50962258; called by muse, mutect2, varscan2
- CHD4 | c.3254G>A p.G1085D (on ENST00000357008 / NM_001363606.2; = p.G1098D on NM_001273.5) | Missense Mutation (SNP) | VAF 151/304 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100537251, COSV58903554; called by muse, mutect2, varscan2
- COASY | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as rs756298801, COSV55897590; called by muse, mutect2, varscan2
- CWC22 | c.2549A>T p.D850V | Missense Mutation (SNP) | VAF 118/259 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); catalogued as COSV55429449; called by muse, mutect2, varscan2
- DNAH5 | c.13844G>A p.R4615H | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408568795, COSV54232489; called by muse, mutect2, varscan2
- DNAH8 | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138892245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFNB1 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs1251392015, COSV52661077; called by muse, mutect2, varscan2
- FBLN5 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs886050888, COSV50904713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCN1 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as rs761311523, COSV65662543; called by muse, mutect2, varscan2
- FLNA | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV61038194; called by muse, mutect2, varscan2
- H2AC21 | c.363_364del p.H124Qfs*? | Frame Shift Del (DEL) | VAF 45/136 reads (33%) | catalogued as rs782632390, COSV58612315; called by mutect2, pindel, varscan2
- HIVEP2 | c.5003C>G p.S1668W | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50019103; called by muse, mutect2, varscan2
- IGKV1D-8 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as rs755041346; called by muse, mutect2, varscan2
- IGSF9B | c.439dup p.Q147Pfs*10 | Frame Shift Ins (INS) | VAF 9/46 reads (20%) | catalogued as rs748943611; called by mutect2, varscan2
- IPO7 | c.2198A>C p.D733A | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65685580; called by muse, mutect2, varscan2
- KIAA0319 | c.1155A>G p.I385M | Missense Mutation (SNP) | VAF 153/379 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV65499413; called by muse, mutect2, varscan2
- KMT2E | c.2685T>A p.Y895* | Nonsense Mutation (SNP) | VAF 62/176 reads (35%) | catalogued as COSV57575098; called by muse, mutect2, varscan2
- LMNTD1 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51447951; called by muse, mutect2, varscan2
- LRP4 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.417); catalogued as rs760783389, COSV66136435, COSV66138092; called by muse, mutect2, varscan2
- LRRC36 | c.177G>T p.R59S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61717960, COSV61719319; called by muse, mutect2, varscan2
- NEBL | c.2793C>G p.S931R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); catalogued as COSV65803695; called by muse, mutect2, varscan2
- NEK1 | c.3223G>A p.D1075N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV71456474; called by muse, mutect2, varscan2
- NKAP | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57630392; called by muse, mutect2, varscan2
- OR2T35 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as rs752074561, COSV58086405; called by muse, mutect2, varscan2
- OTOP3 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs746213958, COSV60912283; called by muse, mutect2, varscan2
- RUSC2 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as rs772001899, COSV63429049; called by muse, mutect2, varscan2
- SLC22A11 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.823); catalogued as rs202093584, COSV57253733, COSV99042485; called by muse, mutect2, varscan2
- SOCS6 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV67546600; called by muse, mutect2, varscan2
- SPATS2 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 98/227 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV58919628; called by muse, mutect2, varscan2
- STX11 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as COSV62449499; called by muse, mutect2, varscan2
- TLN1 | c.6559G>A p.A2187T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as rs201563518, COSV59208563; called by muse, mutect2, varscan2
- TMEM131L | c.2996C>T p.T999M | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs758981167, COSV53645940; called by muse, mutect2, varscan2
- UBR5 | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV55279851; called by muse, mutect2, varscan2
- USP34 | c.3241C>G p.R1081G | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV68402438; called by muse, mutect2, varscan2
- ZFX | c.279T>G p.I93M | Missense Mutation (SNP) | VAF 160/387 reads (41%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.991); catalogued as COSV58448283; called by muse, mutect2, varscan2
- ZNHIT2 | c.720C>G p.F240L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV54205063; called by muse, mutect2, varscan2
- ZSWIM3 | c.1565A>G p.H522R | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs770423327, COSV54848431; called by muse, mutect2, varscan2
- ASB6 | c.498C>T p.A166= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs558817602, COSV52965199; called by muse, mutect2, varscan2
- CLSTN1 | c.2130C>T p.S710= (on ENST00000377298 / NM_001009566.3; = p.S700= on NM_014944.4) | Silent (SNP) | VAF 53/63 reads (84%) | catalogued as rs149931322; called by muse, mutect2, varscan2
- EXOC3L1 | c.720C>T p.V240= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1210740065, COSV52046888; called by muse, mutect2, varscan2
- FAM168B | c.393G>A p.V131= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs982993033, COSV66304216; called by muse, mutect2, varscan2
- ILVBL | c.162C>T p.G54= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as rs1334870342, COSV54620373; called by muse, mutect2, varscan2
- MSTO1 | c.1299G>A p.G433= | Silent (SNP) | VAF 3/55 reads (5%) | catalogued as COSV55472344; called by muse, mutect2
- MUC5B | c.5640C>T p.D1880= | Silent (SNP) | VAF 48/101 reads (48%) | catalogued as rs370168568; called by muse, mutect2, varscan2
- OR4F21 | c.279C>A p.S93= | Silent (SNP) | VAF 175/758 reads (23%) | catalogued as rs1187251405, COSV100307515; called by muse, mutect2, varscan2
- PRPF40B | c.1545C>G p.T515= (on ENST00000380281; = p.T509= on NM_012272.3) | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV56059914; called by muse, mutect2, varscan2
- RASD2 | c.243C>T p.P81= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs751120892, COSV53352231; called by muse, mutect2, varscan2
- SCN5A | c.5067C>T p.D1689= (on ENST00000333535 / NM_198056.3; = p.D1688= on NM_000335.5) | Silent (SNP) | VAF 97/244 reads (40%) | catalogued as rs557836660, COSV61115776; called by muse, mutect2, varscan2
- SIPA1L2 | c.3972C>T p.S1324= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs758251558, COSV53392451; called by muse, mutect2, varscan2
- TIMP2 | c.651C>T p.I217= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs752540256, COSV53159924; called by muse, mutect2, varscan2
- TNK1 | c.1344G>A p.L448= (on ENST00000576812 / NM_001251902.2; = p.L443= on NM_003985.5) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV61171106, COSV61171690; called by muse, varscan2
- TROAP | c.288G>A p.R96= | Silent (SNP) | VAF 70/167 reads (42%) | catalogued as rs1267417851, COSV57744788; called by muse, mutect2, varscan2
- TTN | c.14316A>G p.G4772= (on ENST00000591111; = p.G3845= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 94/211 reads (45%) | catalogued as COSV60132588; called by muse, mutect2, varscan2
- MIR505 | n.7C>A | RNA (SNP) | VAF 156/377 reads (41%) | catalogued as COSV65271497; called by muse, mutect2, varscan2
- NDUFA5 | c.66+452dup | Intron (INS) | VAF 41/106 reads (39%) | called by mutect2, varscan2
- PPP1CC | c.*937G>C | 3'UTR (SNP) | VAF 5/10 reads (50%) | catalogued as COSV58583869; called by muse, mutect2, varscan2
